Somatic mutation profile of tumor specimen TCGA-26-5133-01A (aliquot TCGA-26-5133-01A-01D-1486-08) from TCGA case TCGA-26-5133, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,560 days).
Specimen TCGA-26-5133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695f6c4c-81c1-42a0-9d5f-5e6452a82e2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-5133-10A (Blood Derived Normal), aliquot TCGA-26-5133-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2e54cc7-fc3f-4928-9675-25e245e2c5d4

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 26, Silent 12, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 49/58 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV56475427, COSV56476792; called by muse, mutect2
- AKAP5 | c.1219T>C p.S407P | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57742801; called by muse, mutect2, varscan2
- ATP8B4 | c.2319T>A p.N773K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV52717095; called by muse, mutect2, varscan2
- BAP1 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as rs1221534458, COSV56235291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.2446T>C p.C816R | Missense Mutation (SNP) | VAF 13/385 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1553513870, CM114356, COSV51819769; ClinVar: uncertain significance; called by muse, mutect2
- CX3CR1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs373233918, COSV64193181; called by muse, mutect2
- FMNL2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1334404203, COSV56501143; called by muse, mutect2, varscan2
- HEATR4 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV58575974; called by muse, mutect2, varscan2
- HLA-DMB | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66870810; called by muse, mutect2, varscan2
- IBA57 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812773, COSV64510995, COSV64511185; called by muse, mutect2, varscan2
- IKZF1 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58787328; called by muse, mutect2, varscan2
- KIAA0232 | c.3583C>T p.Q1195* | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV56925956; called by muse, mutect2, varscan2
- LTBP2 | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.78); PolyPhen benign (0.195); catalogued as rs773766117, COSV56209296, COSV99999865; called by muse, mutect2, varscan2
- MAB21L4 | c.671C>T p.P224L (on ENST00000388934 / NM_001085437.3; = p.P56L on NM_024861.4) | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1363786322, COSV56744254; called by muse, mutect2
- MCM3 | c.146G>C p.W49S (on ENST00000229854 / NM_001366374.2; = p.M1? on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV57718845; called by muse, varscan2
- MUTYH | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58344318; called by muse, mutect2, varscan2
- NAAA | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54432577; called by muse, mutect2, varscan2
- NF1 | c.6927del p.P2310Lfs*9 (on ENST00000358273 / NM_001042492.3; = p.P2289Lfs*9 on NM_000267.3) | Frame Shift Del (DEL) | VAF 50/91 reads (55%) | catalogued as COSV62198739, COSV62203540; called by mutect2, pindel, varscan2
- OR11G2 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62132860; called by muse, mutect2, varscan2
- OSBPL8 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53887360; called by muse, mutect2
- SH2D3C | c.1282G>A p.A428T (on ENST00000314830 / NM_170600.3; = p.A271T on NM_005489.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs763971193, COSV59124079; called by muse, mutect2
- SNTB1 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV67326885; called by muse, mutect2, varscan2
- STAT6 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.365); catalogued as COSV55667327; called by muse, mutect2
- TSBP1 | c.1490A>T p.E497V (on ENST00000617061; = p.E502V on NM_006781.5) | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66659428; called by muse, mutect2, varscan2
- U2SURP | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.481); catalogued as COSV67532577; called by muse, mutect2, varscan2
- IGHV3-48 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV3-7 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NF1 | c.7576del p.M2526Wfs*22 (on ENST00000358273 / NM_001042492.3; = p.M2505Wfs*22 on NM_000267.3) | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel*, varscan2*
- PCDHGB1 | c.69_70del p.F23Lfs*44 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by pindel, varscan2
- AL133500.1 | c.1188G>A p.T396= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs146201846, COSV55744616; called by muse, mutect2, varscan2
- ANO6 | c.2676G>A p.V892= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV57665685; called by muse, mutect2
- APOB | c.12531A>G p.R4177= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as COSV51938628; called by muse, mutect2, varscan2
- ATXN7 | c.198C>T p.G66= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs749124142, COSV55754563; called by muse, mutect2, varscan2
- ETFDH | c.297T>C p.R99= | Silent (SNP) | VAF 24/388 reads (6%) | catalogued as COSV57015964; called by muse, mutect2
- GRM4 | c.1770G>A p.L590= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV65214380; called by muse, mutect2, varscan2
- KRT31 | c.1086C>T p.S362= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as rs774179895, COSV52437191; called by muse, mutect2
- NLRP13 | c.1716C>T p.H572= | Silent (SNP) | VAF 16/284 reads (6%) | catalogued as rs1435794055, COSV61623477; called by muse, mutect2
- PCDH15 | c.4110A>G p.L1370= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV57365825; called by muse, mutect2, varscan2
- PLEKHG2 | c.4086T>G p.A1362= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV52687958; called by muse, mutect2
- RHBDL1 | c.1128G>A p.A376= (on ENST00000219551 / NM_001318733.2; = p.A311= on NM_001278720.2) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs771546029, COSV53485811; called by muse, mutect2
- TMEM18 | c.422G>A p.*141= | Silent (SNP) | VAF 101/174 reads (58%) | catalogued as COSV55243701; called by muse, mutect2, varscan2
